Somatic mutation profile of tumor specimen ALCH-B49U-TTP1-A (aliquot ALCH-B49U-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B49U, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 57.7 years (21,074 days).
Specimen ALCH-B49U-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdf7315b-af85-4dce-9d1b-033e8445c8be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B49U-NB1-A (Blood Derived Normal), aliquot ALCH-B49U-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d0c805d-42a0-4859-af48-ad199469101e

The open-access MAF lists 148 somatic variants for this specimen: 101 protein-altering or splice-affecting, 26 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 26, Nonsense Mutation 8, Intron 8, 3'UTR 5, Splice Site 4, RNA 4, 5'Flank 2, Frame Shift Del 2, In Frame Del 2, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OTC | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 66/301 reads (22%) | catalogued as rs72552300, CM910272, COSV50001813; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.783-2A>C p.X261_splice | Splice Site (SNP) | VAF 38/291 reads (13%) | hotspot (GDC flag); catalogued as COSV52818160, COSV52984227, COSV53085853; called by muse, mutect2, varscan2
- ADAD2 | c.1721C>T p.S574L (on ENST00000315906 / NM_001145400.2; = p.S656L on NM_139174.4) | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs760658968; called by muse, mutect2, varscan2
- ADCY10 | c.3004A>G p.K1002E | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs755141272; called by muse, mutect2, varscan2
- ALMS1 | c.3605A>G p.Y1202C | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs772706904; called by muse, mutect2
- ARHGAP45 | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57428724; called by muse, varscan2
- BRCA1 | c.5588A>G p.Y1863C | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1567756242; ClinVar: uncertain significance; called by muse, mutect2
- CACNA1H | c.3267G>C p.K1089N | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.205); catalogued as rs1456869673, COSV62004416, COSV62008894; called by muse, mutect2, varscan2
- CALCOCO1 | c.1206G>T p.K402N | Missense Mutation (SNP) | VAF 30/252 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV100017252; called by muse, mutect2, varscan2
- CD2 | c.974G>A p.G325D | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65643919, COSV65644749; called by muse, mutect2
- CD207 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs782521829, COSV69652041; called by muse, mutect2, varscan2
- CEP295 | c.5683G>A p.D1895N | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs772828192, COSV100292725, COSV57360374; called by muse, mutect2
- CNGB1 | c.1252G>T p.E418* | Nonsense Mutation (SNP) | VAF 48/455 reads (11%) | catalogued as COSV99202862; called by muse, mutect2, varscan2
- CNKSR2 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.727); catalogued as rs770547746, COSV99670195; called by muse, mutect2
- COL22A1 | c.3922G>T p.D1308Y | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100280521; called by muse, mutect2, varscan2
- DENND1B | c.1472A>G p.H491R | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.022); catalogued as rs777362139; called by muse, mutect2
- DGKG | c.1865C>T p.S622L | Missense Mutation (SNP) | VAF 33/275 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs141678179; called by muse, mutect2, varscan2
- FOXG1 | c.1462A>T p.I488L | Missense Mutation (SNP) | VAF 74/433 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.039); catalogued as COSV100486590; called by muse, mutect2, varscan2
- FTCD | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52424585; called by muse, mutect2, varscan2
- HSPA12A | c.1630C>A p.R544S | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as COSV65024134; called by muse, mutect2, varscan2
- MUC16 | c.20104C>T p.P6702S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.839); catalogued as COSV67482563; called by muse, mutect2, varscan2
- PDE9A | c.393G>T p.R131S | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99372290; called by muse, mutect2, varscan2
- SEMA4D | c.2230T>C p.F744L | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs866703536; called by muse, mutect2
- SLC17A6 | c.1669G>A p.G557S | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs767371998; called by muse, mutect2
- SLC44A5 | c.861G>T p.W287C | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV63765026; called by muse, mutect2
- SLIT3 | c.3719G>T p.S1240I | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV60629661; called by muse, mutect2, varscan2
- SOX11 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 21/310 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as rs1403124561; called by muse, mutect2
- SOX2 | c.943T>G p.S315A | Missense Mutation (SNP) | VAF 20/560 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as CD051784; called by muse, mutect2
- TGM6 | c.1182G>T p.E394D | Missense Mutation (SNP) | VAF 84/390 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.879); catalogued as COSV52483487; called by muse, mutect2, varscan2
- TMCO4 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1372503555, COSV99617033; called by muse, mutect2, varscan2
- TMEM135 | c.406A>G p.T136A | Missense Mutation (SNP) | VAF 40/314 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs748586299; called by muse, mutect2, varscan2
- TMEM45A | c.298T>G p.F100V | Missense Mutation (SNP) | VAF 69/766 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100058723; called by muse, mutect2
- TMPRSS11D | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 20/146 reads (14%) | catalogued as COSV52224249, COSV52224347; called by muse, mutect2, varscan2
- TNXB | c.4927C>T p.Q1643* (on ENST00000647633; = p.Q1396* on NM_019105.8 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/170 reads (13%) | catalogued as COSV64481703; called by muse, mutect2, varscan2
- TRDN | c.1321G>T p.A441S | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.321); catalogued as rs930768075; called by muse, mutect2
- TRRAP | c.203G>T p.R68L | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.931); catalogued as COSV62843875; called by muse, mutect2
- ZNF143 | c.1833+3G>A | Splice Region (SNP) | VAF 32/430 reads (7%) | catalogued as COSV55180987; called by muse, mutect2
- ZNF675 | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 29/276 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as rs547912311; called by muse, mutect2, varscan2
- ZNF713 | c.256G>A p.D86N (on ENST00000633730 / NM_001366796.2; = p.D99N on NM_182633.3) | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV68888497; called by muse, mutect2, varscan2
- ZSCAN23 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.278); catalogued as COSV57044026; called by muse, mutect2, varscan2
- ABCA8 | c.1475dup p.P493Afs*2 | Frame Shift Ins (INS) | VAF 12/67 reads (18%) | called by pindel, varscan2
- AMY2B | c.1060A>G p.M354V | Missense Mutation (SNP) | VAF 50/501 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); called by muse, mutect2
- ATP1A2 | c.2242C>A p.L748M | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2
- BIRC6 | c.10174A>T p.I3392F | Missense Mutation (SNP) | VAF 34/459 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.583); called by muse, mutect2
- CASP12 | c.668G>A p.G223D | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); called by muse, mutect2
- CCDC158 | c.1383A>C p.E461D | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.987); called by muse, mutect2
- CD244 | c.82C>A p.H28N | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2
- CDH10 | c.1131T>A p.D377E | Missense Mutation (SNP) | VAF 47/453 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDH7 | c.1484A>T p.Q495L | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CENPF | c.3512C>T p.S1171L | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHST13 | c.973A>G p.M325V | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); called by muse, mutect2
- CTDP1 | c.2298G>T p.Q766H | Missense Mutation (SNP) | VAF 49/256 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CYP3A43 | c.799-1G>T p.X267_splice | Splice Site (SNP) | VAF 12/276 reads (4%) | called by muse, mutect2
- FAM199X | c.505A>T p.K169* | Nonsense Mutation (SNP) | VAF 53/175 reads (30%) | called by muse, mutect2, varscan2
- FANCM | c.800T>A p.I267K | Missense Mutation (SNP) | VAF 49/397 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- GALNTL5 | c.673T>C p.F225L | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GCFC2 | c.715G>C p.E239Q | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- H2BC17 | c.212T>C p.F71S | Missense Mutation (SNP) | VAF 34/268 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HAL | c.836_844del p.G279_A281del | In Frame Del (DEL) | VAF 44/428 reads (10%) | called by mutect2, pindel
- HGF | c.1973G>T p.C658F | Missense Mutation (SNP) | VAF 64/502 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HGS | c.829_831del p.K277del | In Frame Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, varscan2
- IGKV1D-17 | c.33del p.L12Sfs*15 | Frame Shift Del (DEL) | VAF 34/286 reads (12%) | called by mutect2, varscan2
- IRS4 | c.2074T>C p.F692L | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IWS1 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 32/271 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- JPH3 | c.257A>G p.E86G | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KCNT1 | c.469C>A p.L157M (on ENST00000488444; = p.L176M on NM_020822.3) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- LIMK1 | c.1624-1G>T p.X542_splice | Splice Site (SNP) | VAF 17/90 reads (19%) | called by muse, mutect2, varscan2
- LIPC | c.848T>C p.V283A | Missense Mutation (SNP) | VAF 12/350 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- LRRIQ3 | c.1315A>T p.K439* | Nonsense Mutation (SNP) | VAF 21/189 reads (11%) | called by muse, mutect2, varscan2
- MFSD1 | c.809T>G p.F270C | Missense Mutation (SNP) | VAF 26/410 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.05); called by muse, mutect2
- MGAM2 | c.1682G>T p.R561L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC19 | c.17G>T p.W6L | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated, low confidence (0.99); PolyPhen possibly damaging (0.844); called by muse, mutect2
- MYH2 | c.515A>G p.N172S | Missense Mutation (SNP) | VAF 24/546 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NBEA | c.8639G>A p.G2880E | Missense Mutation (SNP) | VAF 34/256 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NUTM2G | c.1124T>A p.I375N | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR10H3 | c.864C>A p.S288R | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR4D5 | c.879A>T p.E293D | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- OR51M1 | c.823C>A p.R275S | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.428); called by muse, mutect2
- OR6F1 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.052); called by muse, mutect2
- OR8B2 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 23/232 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCLO | c.12019A>T p.N4007Y | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- PCLO | c.6167G>C p.R2056T | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2
- PIWIL3 | c.2472G>C p.L824F | Missense Mutation (SNP) | VAF 29/225 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PPM1L | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 45/252 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RDH5 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- RYR2 | c.12832G>T p.D4278Y | Missense Mutation (SNP) | VAF 53/539 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- SLC36A2 | c.884del p.F295Sfs*35 | Frame Shift Del (DEL) | VAF 51/403 reads (13%) | called by mutect2, pindel, varscan2
- SLC44A5 | c.860G>A p.W287* | Nonsense Mutation (SNP) | VAF 12/219 reads (5%) | called by muse, mutect2
- SMYD4 | c.332A>G p.N111S | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SP8 | c.923G>A p.S308N (on ENST00000361443 / NM_198956.4; = p.S326N on NM_182700.6) | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- TAF1L | c.2505G>T p.W835C | Missense Mutation (SNP) | VAF 29/554 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TFR2 | c.13T>A p.W5R | Missense Mutation (SNP) | VAF 48/322 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- THBS3 | c.757-1G>A p.X253_splice | Splice Site (SNP) | VAF 26/150 reads (17%) | called by muse, mutect2, varscan2
- TNXB | c.6769C>T p.P2257S (on ENST00000647633; = p.P2010S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/264 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.94); called by muse, mutect2
- TTN | c.3452C>A p.A1151D (on ENST00000591111; = p.A1105D on NM_003319.4) | Missense Mutation (SNP) | VAF 52/524 reads (10%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC80 | c.9055C>A p.Q3019K | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.163); called by muse, mutect2
- USP26 | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- WDR64 | c.3100C>T p.Q1034* | Nonsense Mutation (SNP) | VAF 22/219 reads (10%) | called by muse, mutect2
- ZNF280B | c.226G>C p.D76H | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.382); called by muse, mutect2
- ZNF292 | c.2072G>A p.G691D | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- ZNF729 | c.1583C>G p.S528C | Missense Mutation (SNP) | VAF 40/433 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.876); called by muse, mutect2
- ADARB2 | c.1935C>T p.S645= | Silent (SNP) | VAF 14/188 reads (7%) | catalogued as rs764627297, COSV67181799; called by muse, mutect2
- CHAMP1 | c.1926T>C p.D642= | Silent (SNP) | VAF 18/292 reads (6%) | called by muse, mutect2
- COPS2 | c.483A>G p.E161= | Silent (SNP) | VAF 20/274 reads (7%) | catalogued as rs774172229; called by muse, mutect2
- FGFRL1 | c.76C>A p.R26= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- GGPS1 | c.270T>C p.N90= | Silent (SNP) | VAF 24/228 reads (11%) | called by muse, mutect2, varscan2
- GLP1R | c.240C>T p.F80= | Silent (SNP) | VAF 19/184 reads (10%) | catalogued as rs145955078; called by muse, mutect2, varscan2
- GLRA3 | c.1293C>T p.I431= | Silent (SNP) | VAF 22/272 reads (8%) | catalogued as COSV56871001; called by muse, mutect2
- GRIK1 | c.933C>A p.G311= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as rs779436393; called by muse, varscan2
- KCNK18 | c.486T>C p.S162= | Silent (SNP) | VAF 28/360 reads (8%) | catalogued as rs1280753048; called by muse, mutect2
- KLHL24 | c.537A>T p.S179= | Silent (SNP) | VAF 37/180 reads (21%) | called by muse, mutect2, varscan2
- KRT86 | c.999G>A p.T333= | Silent (SNP) | VAF 50/738 reads (7%) | catalogued as rs374471358; called by muse, mutect2
- LRRC15 | c.843G>A p.L281= | Silent (SNP) | VAF 22/234 reads (9%) | called by muse, mutect2
- MLH3 | c.573T>C p.N191= | Silent (SNP) | VAF 23/104 reads (22%) | called by muse, mutect2, varscan2
- NCAM2 | c.798C>T p.L266= | Silent (SNP) | VAF 12/149 reads (8%) | called by muse, mutect2
- NUTM2G | c.1125C>A p.I375= | Silent (SNP) | VAF 54/184 reads (29%) | catalogued as rs776189451; called by muse, mutect2, varscan2
- OBSCN | c.3063G>A p.K1021= | Silent (SNP) | VAF 34/334 reads (10%) | called by muse, mutect2, varscan2
- PAQR6 | c.498C>T p.L166= (on ENST00000292291 / NM_001272108.2; = p.L60= on NM_024897.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/127 reads (13%) | called by muse, mutect2, varscan2
- POMGNT2 | c.1056C>T p.T352= | Silent (SNP) | VAF 17/164 reads (10%) | called by muse, mutect2, varscan2
- RAG1 | c.1128C>T p.I376= | Silent (SNP) | VAF 72/762 reads (9%) | catalogued as COSV55025669; called by muse, mutect2
- RNF167 | c.72G>T p.G24= | Silent (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- RYR1 | c.9589C>T p.L3197= | Silent (SNP) | VAF 10/117 reads (9%) | called by muse, mutect2
- RYR2 | c.12216G>T p.T4072= | Silent (SNP) | VAF 23/324 reads (7%) | catalogued as COSV100772134, COSV63702567; called by muse, mutect2
- SCN2A | c.2529G>A p.V843= | Silent (SNP) | VAF 25/370 reads (7%) | called by muse, mutect2
- TMC2 | c.2139C>T p.T713= | Silent (SNP) | VAF 26/165 reads (16%) | called by muse, mutect2, varscan2
- TRANK1 | c.8064G>T p.L2688= | Silent (SNP) | VAF 42/231 reads (18%) | called by muse, mutect2, varscan2
- ZNF729 | c.1785T>A p.T595= | Silent (SNP) | VAF 30/400 reads (8%) | called by muse, mutect2
- AC005041.1 | chr2:74391852 del C | 3'Flank (DEL) | VAF 17/164 reads (10%) | called by mutect2, pindel, varscan2
- ADAM21P1 | n.1885C>G | RNA (SNP) | VAF 22/209 reads (11%) | called by muse, mutect2, varscan2
- AFF3 | chr2:100105865 C>A | 5'Flank (SNP) | VAF 42/351 reads (12%) | catalogued as rs1359631349, COSV57841777; called by muse, mutect2, varscan2
- CRIM1 | c.2429-5475G>A | Intron (SNP) | VAF 7/235 reads (3%) | called by muse, mutect2
- CSMD3 | c.178+59887G>T | Intron (SNP) | VAF 56/778 reads (7%) | called by muse, mutect2
- CSMD3 | c.178+59886G>T | Intron (SNP) | VAF 56/776 reads (7%) | called by muse, mutect2
- DCAF17 | c.*3166C>A | 3'UTR (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- DPPA3P2 | n.331G>A | RNA (SNP) | VAF 65/374 reads (17%) | called by muse, mutect2
- ICA1 | c.256+781dup | Intron (INS) | VAF 33/165 reads (20%) | called by mutect2, pindel, varscan2
- LGI1 | c.*24T>C | 3'UTR (SNP) | VAF 26/334 reads (8%) | catalogued as rs755405168; called by muse, mutect2
- PNO1 | chr2:68157658 T>C | 5'Flank (SNP) | VAF 7/55 reads (13%) | catalogued as rs558219770; called by muse, varscan2
- PTPRB | c.4060+24A>G | Intron (SNP) | VAF 9/60 reads (15%) | catalogued as rs780396411; called by muse, varscan2
- RPS27A | c.103+33C>T | Intron (SNP) | VAF 55/317 reads (17%) | catalogued as rs373687449; called by muse, mutect2, varscan2
- SIRPB1 | c.76+14964C>A | Intron (SNP) | VAF 32/282 reads (11%) | called by muse, mutect2, varscan2
- SREBF2 | c.*36G>T | 3'UTR (SNP) | VAF 25/121 reads (21%) | catalogued as COSV100761380; called by muse, mutect2, varscan2
- SSPOP | n.3237G>A | RNA (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- TBC1D3P1 | n.102G>A | RNA (SNP) | VAF 37/296 reads (13%) | catalogued as rs1329989645; called by muse, mutect2, varscan2
- UBR7 | c.*1443C>T | 3'UTR (SNP) | VAF 70/395 reads (18%) | called by muse, mutect2, varscan2
- VCAN | c.*14G>T | 3'UTR (SNP) | VAF 57/517 reads (11%) | called by muse, mutect2, varscan2
- ZNF569 | c.-27C>T | 5'UTR (SNP) | VAF 15/95 reads (16%) | catalogued as rs1362474078; called by muse, mutect2
- ZNF608 | c.907-8989del | Intron (DEL) | VAF 16/107 reads (15%) | called by mutect2, pindel, varscan2
